Somatic mutation profile of tumor specimen TCGA-22-4596-01A (aliquot TCGA-22-4596-01A-01D-1267-08) from TCGA case TCGA-22-4596, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 69.7 years (25,448 days).
Specimen TCGA-22-4596-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7339195f-894d-4f10-915f-ec75a2036e4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-4596-11A (Solid Tissue Normal), aliquot TCGA-22-4596-11A-01D-1267-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb82353e-5b58-4212-82e9-1466ca410a43

The open-access MAF lists 128 somatic variants for this specimen: 97 protein-altering or splice-affecting, 29 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 29, Nonsense Mutation 4, Splice Site 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGBL1 | c.3015G>T p.E1005D | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.056); catalogued as COSV101223349; called by muse, mutect2, varscan2
- AGXT2 | c.161T>C p.M54T | Missense Mutation (SNP) | VAF 42/470 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99183770; called by muse, mutect2
- AKR1C1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1554769934, COSV101080487; called by muse, mutect2
- APP | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV100695881; called by muse, mutect2
- ATG4A | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 36/1036 reads (3%) | SIFT tolerated (0.79); PolyPhen benign (0.026); catalogued as COSV100619537; called by muse, mutect2
- ATP10B | c.3595A>T p.M1199L | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100515167; called by muse, mutect2
- ATP10B | c.1304C>A p.T435K | Missense Mutation (SNP) | VAF 79/484 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100469473, COSV58778150; called by muse, mutect2, varscan2
- ATP6V0A2 | c.712G>C p.V238L | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV100377045; called by muse, mutect2
- C9orf72 | c.610A>G p.T204A | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101186525; called by muse, mutect2, varscan2
- CASD1 | c.1033A>G p.T345A | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs1161050016, COSV99802632, COSV99802689; called by muse, mutect2, varscan2
- CAV1 | c.20T>C p.V7A | Missense Mutation (SNP) | VAF 107/578 reads (19%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV100591953; called by muse, mutect2, varscan2
- CCDC18 | c.2457+1G>C p.X819_splice (on ENST00000343253 / NM_001306076.1; = p.X820_splice on NM_206886.4) | Splice Site (SNP) | VAF 15/143 reads (10%) | catalogued as COSV100159676; called by muse, mutect2, varscan2
- CENPF | c.3998G>A p.R1333K | Missense Mutation (SNP) | VAF 8/244 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100871724; called by muse, mutect2
- CFAP47 | c.5311T>A p.C1771S | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV100545425; called by muse, mutect2
- CHD1L | c.1340A>C p.N447T | Missense Mutation (SNP) | VAF 14/384 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100787484; called by muse, mutect2
- CNTNAP5 | c.1380C>A p.N460K | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as COSV101443670; called by muse, mutect2
- COL22A1 | c.4538G>T p.R1513L | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as rs200298766, COSV100278836, COSV57343458; called by muse, mutect2, varscan2
- CSMD3 | c.6253C>G p.Q2085E (on ENST00000297405 / NM_001363185.1; = p.Q1981E on NM_052900.3) | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as COSV99836685; called by muse, mutect2, varscan2
- CTPS2 | c.1219A>G p.I407V | Missense Mutation (SNP) | VAF 23/255 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100826891; called by muse, mutect2
- DDX27 | c.202G>T p.G68C | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.41); catalogued as COSV100874713, COSV65630525; called by muse, mutect2, varscan2
- DDX42 | c.2656A>G p.R886G | Missense Mutation (SNP) | VAF 35/427 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.026); catalogued as COSV100834954; called by muse, mutect2
- ETV2 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99876904; called by muse, mutect2, varscan2
- FEM1B | c.857A>G p.D286G | Missense Mutation (SNP) | VAF 21/385 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100183684; called by muse, mutect2
- GALNT17 | c.692T>A p.I231N | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.944); catalogued as COSV100354168; called by muse, mutect2
- GPR35 | c.493A>G p.S165G | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.129); catalogued as COSV100166511; called by muse, mutect2
- GPRASP2 | c.2285C>T p.S762L | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100176548; called by muse, mutect2
- GRID2 | c.1729G>C p.V577L | Missense Mutation (SNP) | VAF 39/376 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.152); catalogued as COSV99941799; called by muse, mutect2
- HOXB5 | c.203C>A p.A68E | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV53313823, COSV99494570; called by muse, mutect2, varscan2
- IGFLR1 | c.311G>A p.G104D | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as rs762122644, COSV99495192; called by muse, mutect2, varscan2
- IRS4 | c.2770A>T p.M924L | Missense Mutation (SNP) | VAF 86/1760 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100929595; called by muse, mutect2
- JMJD1C | c.2336C>G p.T779S | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV101232431; called by muse, mutect2, varscan2
- KIAA1549L | c.3581C>T p.T1194M (on ENST00000321505; = p.T1491M on NM_012194.3) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs558635917, COSV55771747; called by muse, mutect2
- KLHL4 | c.1036T>A p.F346I | Missense Mutation (SNP) | VAF 13/232 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV100909708; called by muse, mutect2
- KNDC1 | c.4721C>T p.S1574F | Missense Mutation (SNP) | VAF 116/1252 reads (9%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.914); catalogued as COSV100465166; called by muse, mutect2
- KNOP1 | c.912G>A p.W304* | Nonsense Mutation (SNP) | VAF 106/1318 reads (8%) | catalogued as COSV99575218; called by muse, mutect2
- KPNA1 | c.1490T>C p.F497S | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as COSV100724247; called by muse, mutect2
- MAGED1 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.771); catalogued as COSV100431633; called by muse, mutect2, varscan2
- MIDEAS | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99678946; called by muse, mutect2
- MORC4 | c.1660G>T p.D554Y | Missense Mutation (SNP) | VAF 28/858 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as rs868172752, COSV99717292; called by muse, mutect2
- MUC17 | c.10958G>T p.G3653V | Missense Mutation (SNP) | VAF 68/453 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV100071473, COSV100073744; called by muse, varscan2
- NCF2 | c.611T>C p.V204A | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100838905; called by muse, mutect2
- NLN | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 30/230 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV101114328; called by muse, mutect2, varscan2
- NLRC3 | c.1961T>A p.M654K | Missense Mutation (SNP) | VAF 67/384 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100072901; called by muse, mutect2, varscan2
- NPBWR2 | c.581T>A p.V194D | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.828); catalogued as COSV100871124; called by muse, mutect2, varscan2
- NRXN1 | c.1105G>T p.D369Y | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100455471; called by muse, mutect2
- NTM | c.486A>T p.R162S | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100868716; called by muse, mutect2
- NUFIP1 | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.572); catalogued as COSV100742133; called by mutect2, varscan2
- OR12D2 | c.703A>T p.K235* | Nonsense Mutation (SNP) | VAF 22/468 reads (5%) | catalogued as COSV101011312; called by muse, mutect2
- OR2F2 | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 30/415 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as rs755644378, COSV101283840, COSV68833146; called by muse, mutect2
- OR2M5 | c.768G>T p.L256F | Missense Mutation (SNP) | VAF 24/686 reads (3%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.71); catalogued as COSV100822829; called by muse, mutect2
- OR2T10 | c.450T>G p.F150L | Missense Mutation (SNP) | VAF 12/381 reads (3%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV100393729; called by muse, mutect2
- OR5L1 | c.17G>C p.C6S | Missense Mutation (SNP) | VAF 50/558 reads (9%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.584); catalogued as COSV100449884, COSV61734979; called by muse, mutect2
- OR6T1 | c.174G>C p.Q58H | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV100190006, COSV58306045; called by muse, mutect2
- OR8K1 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV54403400; called by muse, mutect2, varscan2
- OSTF1 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 29/295 reads (10%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.993); catalogued as COSV100653756; called by muse, mutect2
- PCDH18 | c.807T>A p.N269K | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100787363; called by muse, mutect2
- PCDHA10 | c.986T>C p.M329T | Missense Mutation (SNP) | VAF 84/363 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); catalogued as rs374158544; called by muse, mutect2, varscan2
- PCNX4 | c.853A>T p.M285L (on ENST00000406854 / NM_001330177.2; = p.M51L on NM_022495.5) | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.437); catalogued as COSV100470425; called by muse, mutect2
- PDE6A | c.1659C>A p.Y553* | Nonsense Mutation (SNP) | VAF 16/223 reads (7%) | catalogued as COSV54928911, COSV99678363; called by muse, mutect2
- PIWIL4 | c.2062A>T p.I688L | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); catalogued as rs767622103, COSV100133262; called by muse, mutect2, varscan2
- PSG4 | c.1003C>A p.P335T | Missense Mutation (SNP) | VAF 44/514 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99737236; called by muse, mutect2
- PTPN14 | c.1957A>G p.M653V | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100872686; called by muse, mutect2
- PTPRB | c.618G>T p.E206D | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100547338; called by muse, mutect2
- PXDNL | c.3643C>T p.L1215F | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.169); catalogued as rs372280221; called by muse, mutect2
- RHOH | c.480G>T p.Q160H | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101110520; called by muse, mutect2, varscan2
- SAMD9L | c.2045C>A p.S682* | Nonsense Mutation (SNP) | VAF 34/204 reads (17%) | catalogued as COSV100560801; called by muse, mutect2, varscan2
- SCN1A | c.5533A>C p.N1845H (on ENST00000303395 / NM_001202435.3; = p.N1834H on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/327 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100320778; called by muse, mutect2
- SF3B2 | c.974G>C p.R325P | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100488460; called by muse, mutect2
- SGIP1 | c.958C>G p.P320A | Missense Mutation (SNP) | VAF 51/481 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV99391797; called by muse, mutect2, varscan2
- SIDT2 | c.1193G>T p.R398L | Missense Mutation (SNP) | VAF 46/339 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.061); catalogued as COSV99637825; called by muse, mutect2, varscan2
- SLC4A3 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs753042417, COSV56095970, COSV56097598; called by muse, mutect2, varscan2
- SLC6A11 | c.1792G>A p.G598S | Missense Mutation (SNP) | VAF 64/343 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as COSV54390102; called by muse, mutect2, varscan2
- SLC7A8 | c.1082G>T p.R361L | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.454); catalogued as COSV100328461; called by muse, mutect2, varscan2
- SLITRK3 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 17/388 reads (4%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.994); catalogued as COSV99579406; called by muse, mutect2
- SLITRK6 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 34/248 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV101233248; called by muse, mutect2, varscan2
- SMURF2 | c.1619A>G p.D540G | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99300785; called by muse, mutect2
- SUGCT | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100002397; called by muse, mutect2
- SYNE2 | c.20590C>G p.Q6864E | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV100647866; called by muse, mutect2
- TGM4 | c.1192G>A p.V398M | Missense Mutation (SNP) | VAF 74/379 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV99942390; called by muse, mutect2, varscan2
- TMCO2 | c.424A>G p.N142D | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101033771; called by muse, mutect2
- TMEM132B | c.1930G>T p.A644S | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100169922; called by muse, varscan2
- TMEM225 | c.523C>A p.H175N | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.647); catalogued as COSV100902818; called by muse, mutect2
- TNFRSF17 | c.35A>C p.E12A | Missense Mutation (SNP) | VAF 195/887 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99273271; called by muse, mutect2, varscan2
- TRPS1 | c.2882A>G p.E961G (on ENST00000220888 / NM_001330599.2; = p.E974G on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/552 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99631552; called by muse, mutect2, varscan2
- TSSK2 | c.734G>C p.C245S | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV99350956; called by muse, mutect2
- USP20 | c.1480C>G p.Q494E | Missense Mutation (SNP) | VAF 20/407 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as COSV100204395; called by muse, mutect2
- ZC4H2 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 22/349 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.066); catalogued as rs1216371565, COSV100565005; called by muse, mutect2
- ZNF101 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV100543560; called by muse, mutect2
- ZNF317 | c.526G>T p.G176C | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as COSV99927165; called by muse, mutect2
- ZNF423 | c.208G>A p.E70K (on ENST00000563137 / NM_001379286.1; = p.E62K on NM_015069.4) | Missense Mutation (SNP) | VAF 114/714 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.691); catalogued as COSV99282118; called by muse, mutect2, varscan2
- ZNF519 | c.1151C>A p.A384D | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as COSV101645575; called by muse, mutect2
- ZNF581 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs747956283, COSV99553148; called by mutect2, varscan2
- ZNF804B | c.2306T>C p.I769T | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100304219; called by muse, mutect2
- MFAP3L | c.394G>C p.G132R | Missense Mutation (SNP) | VAF 54/362 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, varscan2
- PCDHB8 | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 25/513 reads (5%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.006); called by muse, mutect2
- UBA6 | c.1791G>T p.K597N | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF84 | c.488A>T p.N163I | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- ACSM3 | c.687C>A p.I229= | Silent (SNP) | VAF 47/586 reads (8%) | catalogued as COSV99184571; called by muse, mutect2
- ADCY8 | c.2040C>T p.G680= | Silent (SNP) | VAF 26/334 reads (8%) | catalogued as rs149781974, COSV53924371; called by muse, mutect2
- BRINP2 | c.1536G>T p.L512= | Silent (SNP) | VAF 16/206 reads (8%) | catalogued as COSV100838136; called by muse, mutect2
- C3orf70 | c.627A>G p.E209= | Silent (SNP) | VAF 24/286 reads (8%) | catalogued as COSV100621265; called by muse, mutect2
- C7 | c.120T>C p.N40= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV100495947; called by muse, mutect2
- CEP128 | c.2700A>G p.Q900= | Silent (SNP) | VAF 10/184 reads (5%) | catalogued as rs1158840032, COSV99824953; called by muse, mutect2
- CNTNAP2 | c.1461C>G p.P487= | Silent (SNP) | VAF 24/340 reads (7%) | called by muse, mutect2
- ELF4 | c.801G>A p.R267= | Silent (SNP) | VAF 33/923 reads (4%) | catalogued as COSV100257409; called by muse, mutect2
- FANCG | c.1821C>T p.A607= | Silent (SNP) | VAF 10/244 reads (4%) | catalogued as COSV100734236, COSV62719746; called by muse, mutect2
- FLG | c.10149A>C p.S3383= | Silent (SNP) | VAF 44/1251 reads (4%) | catalogued as COSV100911647, COSV64251011; called by muse, mutect2
- GMPS | c.1767C>T p.R589= | Silent (SNP) | VAF 51/461 reads (11%) | catalogued as COSV99903204; called by muse, mutect2, varscan2
- GUCY2F | c.2385T>C p.A795= | Silent (SNP) | VAF 21/475 reads (4%) | catalogued as COSV99485138; called by muse, mutect2
- KCNS2 | c.1020T>A p.I340= | Silent (SNP) | VAF 20/322 reads (6%) | catalogued as COSV99751217; called by muse, mutect2
- LYZL6 | c.270G>A p.S90= | Silent (SNP) | VAF 18/206 reads (9%) | catalogued as rs115295324; called by muse, mutect2
- MCAM | c.498G>T p.G166= | Silent (SNP) | VAF 42/254 reads (17%) | catalogued as COSV99877808; called by muse, mutect2, varscan2
- MTARC1 | c.570A>G p.R190= | Silent (SNP) | VAF 4/80 reads (5%) | catalogued as COSV100856320; called by muse, mutect2
- NRDE2 | c.840A>C p.T280= | Silent (SNP) | VAF 44/432 reads (10%) | catalogued as COSV100583513; called by muse, mutect2
- OR6B1 | c.249T>C p.F83= | Silent (SNP) | VAF 36/521 reads (7%) | catalogued as rs762479220, COSV101281658; called by muse, mutect2
- PPP1R9A | c.48C>T p.A16= | Silent (SNP) | VAF 8/189 reads (4%) | catalogued as COSV99195993; called by muse, mutect2
- PPP2R5C | c.600C>T p.I200= | Silent (SNP) | VAF 40/604 reads (7%) | catalogued as COSV100159594; called by muse, mutect2
- PRAMEF12 | c.309G>A p.L103= | Silent (SNP) | VAF 67/768 reads (9%) | catalogued as rs1388703280, COSV100743326; called by muse, mutect2
- PRR22 | c.1098G>A p.P366= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as rs751932444, COSV57832115; called by muse, mutect2, varscan2
- SLC36A3 | c.702C>T p.I234= | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as COSV100077507; called by muse, mutect2
- SLITRK4 | c.1545G>C p.G515= | Silent (SNP) | VAF 18/530 reads (3%) | catalogued as rs1556426726, COSV100567378, COSV62022813; called by muse, mutect2
- SMPDL3A | c.1014T>C p.F338= | Silent (SNP) | VAF 48/304 reads (16%) | catalogued as COSV100868709; called by muse, mutect2, varscan2
- SNAPC2 | c.243G>A p.V81= | Silent (SNP) | VAF 38/224 reads (17%) | catalogued as COSV99684069; called by muse, mutect2, varscan2
- WSCD1 | c.36C>T p.L12= | Silent (SNP) | VAF 18/198 reads (9%) | catalogued as COSV100496637; called by muse, mutect2
- ZNF182 | c.405T>A p.R135= | Silent (SNP) | VAF 15/208 reads (7%) | catalogued as COSV100527082; called by muse, mutect2
- ZNF479 | c.99G>T p.L33= | Silent (SNP) | VAF 35/255 reads (14%) | catalogued as COSV100482785; called by muse, mutect2, varscan2
- AL645922.1 | c.256+573C>T | Intron (SNP) | VAF 22/156 reads (14%) | catalogued as rs140767210; called by muse, mutect2, varscan2
- FRMPD2B | n.1188T>A | RNA (SNP) | VAF 30/212 reads (14%) | called by mutect2, varscan2
